Somatic mutation profile of tumor specimen TCGA-EC-A1NJ-01A (aliquot TCGA-EC-A1NJ-01A-31D-A14G-09) from TCGA case TCGA-EC-A1NJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 73.9 years (27,002 days).
Specimen TCGA-EC-A1NJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 025d332a-9a59-4b6c-9040-298dcb2b6f96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EC-A1NJ-10A (Blood Derived Normal), aliquot TCGA-EC-A1NJ-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66806abb-fde4-447c-a7db-5f5845405a97

The open-access MAF lists 307 somatic variants for this specimen: 231 protein-altering or splice-affecting, 71 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 71, Frame Shift Ins 43, Frame Shift Del 6, Splice Site 5, Splice Region 3, Nonsense Mutation 2, Intron 2, Translation Start Site 1, 3'UTR 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BARD1 | c.623dup p.K209Efs*5 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | catalogued as rs587780033; ClinVar: pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352dup p.R785Qfs*23 (on ENST00000651564; = p.R738Qfs*23 on NM_015692.5) | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.2299T>C p.S767P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV101201025; called by muse, mutect2, varscan2
- ABLIM3 | c.1501A>G p.R501G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100448126; called by muse, varscan2
- ABT1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs782050243, COSV51291061; called by muse, mutect2, varscan2
- ACAT1 | c.349A>C p.T117P | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99759131; called by muse, mutect2, varscan2
- ACOXL | c.664A>G p.R222G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1449221045, COSV100489942; called by muse, mutect2
- ACSM2A | c.50A>C p.Q17P | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV99524948; called by muse, mutect2, varscan2
- ACVR1B | c.1518A>C p.*506Yext*68 | Nonstop Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99231295; called by muse, mutect2, varscan2
- ADAMTS20 | c.2279A>G p.D760G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV101166094; called by muse, mutect2, varscan2
- ADGRV1 | c.6421A>G p.T2141A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1400121092, COSV101315569; called by muse, mutect2, varscan2
- AKT1 | c.238T>C p.W80R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV62571792, COSV62572815; called by muse, mutect2, varscan2
- ALKBH7 | c.381C>T p.F127= | Splice Region (SNP) | VAF 19/59 reads (32%) | catalogued as COSV99831690; called by muse, mutect2, varscan2
- ALX1 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100374307; called by muse, mutect2, varscan2
- AMPD3 | c.1499T>C p.L500P (on ENST00000396553 / NM_001025389.2; = p.L509P on NM_000480.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67332126; called by muse, mutect2, varscan2
- ANK3 | c.4057A>G p.R1353G (on ENST00000280772 / NM_001320874.2; = p.R487G on NM_001149.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1564890484, COSV99778696; called by muse, mutect2, varscan2
- ANKRD28 | c.1961A>G p.Q654R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as COSV101080222; called by muse, mutect2, varscan2
- APC | c.413A>G p.E138G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV57353370; called by muse, mutect2, varscan2
- ASB12 | c.736T>C p.F246L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100744618; called by muse, mutect2, varscan2
- ASF1B | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99654237; called by muse, varscan2
- ATP2B3 | c.1658A>G p.D553G | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV99683333; called by muse, mutect2, varscan2
- BCL9L | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100599621; called by muse, mutect2, varscan2
- BRD1 | c.2831C>T p.P944L (on ENST00000216267 / NM_001349940.1; = p.P1075L on NM_001304808.3) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1296112579, COSV53455827, COSV99349334; called by muse, mutect2, varscan2
- C10orf71 | c.1167dup p.G390Rfs*39 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs748396302; called by mutect2, pindel, varscan2
- C2CD5 | c.669A>T p.L223F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.76); catalogued as COSV100448525; called by muse, mutect2, varscan2
- C8orf74 | c.804dup p.I269Hfs*51 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as rs773207825; called by pindel, varscan2
- C9orf135 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs145598805; called by muse, mutect2, varscan2
- CACNA2D3 | c.3028A>G p.M1010V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV99871147; called by muse, mutect2, varscan2
- CAMLG | c.659T>C p.L220S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777703; called by muse, mutect2, varscan2
- CANX | c.1313T>G p.F438C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99910277; called by muse, mutect2, varscan2
- CAPN6 | c.809A>G p.E270G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100136748; called by muse, mutect2, varscan2
- CCDC130 | c.671A>G p.D224G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99237277; called by muse, mutect2, varscan2
- CCDC78 | c.745C>A p.H249N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as COSV99557240; called by muse, mutect2, varscan2
- CCN1 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV101486117, COSV71704291; called by muse, mutect2, varscan2
- CDHR1 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100258516; called by muse, mutect2, varscan2
- CDHR2 | c.1327A>G p.R443G | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV99991152; called by muse, mutect2, varscan2
- CHD3 | c.2573T>C p.L858P | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100390822; called by muse, mutect2, varscan2
- CHD5 | c.2575-2A>G p.X859_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99312731; called by muse, mutect2, varscan2
- COL27A1 | c.2659A>G p.K887E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1251021882, COSV100620770; called by muse, mutect2
- COL4A1 | c.1717A>G p.K573E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs1006335866, COSV101010994; called by muse, mutect2, varscan2
- COL4A4 | c.1841T>C p.F614S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100306374; called by mutect2, varscan2
- COL6A1 | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.755); catalogued as rs1569518085, COSV100720002; called by muse, mutect2, varscan2
- COMMD4 | c.184T>C p.S62P | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99143112; called by muse, mutect2, varscan2
- COQ10B | c.41T>A p.V14D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99827286; called by muse, mutect2, varscan2
- CPNE1 | c.1186A>G p.N396D (on ENST00000352393; = p.N401D on NM_003915.5) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs1261447587, COSV100467128; called by muse, mutect2, varscan2
- CTNNA1 | c.1621A>G p.T541A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.088); catalogued as COSV100242279; called by mutect2, varscan2
- CXCL1 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV101203912; called by muse, mutect2, varscan2
- DLGAP2 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); catalogued as rs532491856, COSV70095288; called by muse, mutect2, varscan2
- DMBT1 | c.3566T>C p.V1189A (on ENST00000338354 / NM_001377530.1; = p.V690A on NM_004406.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100351959, COSV100352347; called by muse, mutect2, varscan2
- DNAH1 | c.9041C>T p.P3014L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs376968517; called by muse, mutect2, varscan2
- DNASE2 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV99262461; called by muse, mutect2, varscan2
- DOCK9 | c.5311A>G p.M1771V (on ENST00000376460 / NM_001366676.2; = p.M1772V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0.031); catalogued as rs764339819, COSV100238208; called by muse, mutect2, varscan2
- EAF2 | c.334dup p.T112Nfs*4 | Frame Shift Ins (INS) | VAF 8/15 reads (53%) | catalogued as rs746509911; called by mutect2, varscan2
- ECT2L | c.2300T>C p.I767T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs544168481, COSV100871788; called by muse, mutect2, varscan2
- EED | c.923A>T p.Y308F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54556403; called by muse, mutect2, varscan2
- EHMT2 | c.2287A>G p.N763D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV100977132; called by muse, mutect2, varscan2
- EP300 | c.3593A>T p.Y1198F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99607654; called by muse, mutect2, varscan2
- ERICH3 | c.1685A>G p.N562S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100443611; called by muse, mutect2, varscan2
- FAM50A | c.780+2T>C p.X260_splice | Splice Site (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99340889; called by muse, mutect2
- FGD3 | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV100490436; called by muse, mutect2
- FOCAD | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as rs751441485, COSV100620119, COSV58106211; called by muse, varscan2
- GPER1 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99866780; called by muse, mutect2, varscan2
- GPS1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs1407346478, COSV100135878; called by muse, mutect2, varscan2
- GTF3C1 | c.5541dup p.E1848Rfs*22 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | catalogued as rs763161381; called by mutect2, varscan2
- GUCY1A1 | c.805A>C p.S269R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.229); catalogued as COSV99637279; called by muse, mutect2, varscan2
- GUCY1B1 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs548993170, COSV100025359, COSV100025588; called by muse, mutect2, varscan2
- HAT1 | c.1214T>C p.L405P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99907828; called by muse, mutect2, varscan2
- HEATR5A | c.1210A>G p.N404D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV101119692; called by muse, mutect2, varscan2
- HTT | c.7876A>G p.N2626D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as rs757552793; called by muse, mutect2, varscan2
- IGSF21 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.267); catalogued as rs267598244, COSV52124620; called by muse, mutect2, varscan2
- IL23R | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100724625; called by muse, mutect2
- ITGAX | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs767824543, COSV99191500; called by muse, mutect2, varscan2
- ITGAX | c.2712C>A p.N904K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763066244, COSV99191502; called by muse, mutect2, varscan2
- KDM5A | c.1029+2T>G p.X343_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as COSV101238640; called by muse, mutect2, varscan2
- KIDINS220 | c.3236A>G p.Y1079C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs760475551, COSV56757155; called by muse, mutect2
- KRT10 | c.157A>G p.S53G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99509942; called by muse, mutect2, varscan2
- LCTL | c.214A>C p.S72R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100427158; called by muse, mutect2, varscan2
- MACO1 | c.306dup p.A103Cfs*3 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | catalogued as rs752439249; called by mutect2, varscan2
- MARK3 | c.1057A>G p.K353E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53511817, COSV99357902; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MET | c.2564A>G p.E855G | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100577062; called by muse, mutect2, varscan2
- MISP | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs45591331; called by muse, mutect2, varscan2
- MPP2 | c.1343G>A p.G448D (on ENST00000461854 / NM_001278372.2; = p.G424D on NM_005374.5) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1227380951, COSV99290076; called by mutect2, varscan2
- MTCL1 | c.3208C>T p.P1070S (on ENST00000306329 / NM_001378206.1; = p.P751S on NM_015210.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV60403755; called by muse, mutect2, varscan2
- MTOR | c.5746T>C p.W1916R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100815793; called by muse, mutect2, varscan2
- MYCBP2 | c.11941A>G p.M3981V (on ENST00000357337; = p.M4019V on NM_015057.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV62010170; called by muse, mutect2, varscan2
- MYT1 | c.2501T>C p.L834P | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100114117; called by muse, mutect2, varscan2
- NAGLU | c.1747T>C p.Y583H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99864012; called by muse, mutect2, varscan2
- NAV2 | c.6920G>T p.R2307L (on ENST00000396087 / NM_001244963.2; = p.R2248L on NM_145117.5) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100216329, COSV60665583; called by muse, mutect2, varscan2
- NBEAL2 | c.4366C>T p.R1456C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs778773407, COSV99434794; called by muse, mutect2, varscan2
- NEBL | c.2990A>G p.Q997R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101009116; called by muse, mutect2, varscan2
- NECTIN2 | c.1594A>G p.M532V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1177017816, COSV99374810; called by muse, mutect2, varscan2
- NLRP1 | c.3419A>G p.N1140S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.082); catalogued as COSV99333217; called by muse, mutect2, varscan2
- NOL4 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99305399; called by muse, mutect2, varscan2
- NOTCH4 | c.5991A>C p.Q1997H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.06); catalogued as COSV100900451; called by muse, mutect2, varscan2
- NPR1 | c.2775T>A p.D925E | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100901989; called by muse, mutect2, varscan2
- NPRL3 | c.1498A>G p.S500G (on ENST00000611875 / NM_001077350.3; = p.S475G on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV99549840; called by muse, mutect2, varscan2
- NSD1 | c.2665C>T p.L889F | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100728553; called by muse, mutect2, varscan2
- NSMAF | c.1762A>G p.S588G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV99232452; called by muse, mutect2, varscan2
- NUP62 | c.1148A>G p.K383R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100351834; called by muse, mutect2, varscan2
- OPA3 | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV99619800; called by muse, mutect2
- OR10J1 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV101419803, COSV71128289; called by muse, mutect2, varscan2
- OR2T2 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as COSV100737586; called by muse, mutect2, varscan2
- OR9G1 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100380280; called by muse, mutect2, varscan2
- OTUB2 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.889); catalogued as COSV99180147; called by muse, mutect2, varscan2
- OXR1 | c.2487A>G p.G829= (on ENST00000442977 / NM_001198532.1; = p.G801= on NM_018002.3) | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99860819; called by muse, mutect2, varscan2
- PAPOLB | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as COSV101271290; called by muse, mutect2, varscan2
- PAX7 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs769536224, COSV100946625; called by muse, mutect2, varscan2
- PCDHA9 | c.587T>C p.L196S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs560003824, COSV100969155; called by muse, mutect2, varscan2
- PCDHGB2 | c.892dup p.T298Nfs*9 | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | catalogued as rs758957504; called by mutect2, varscan2
- PCNX2 | c.5344G>A p.V1782I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183609426, COSV50781512; called by muse, mutect2, varscan2
- PDCD6IP | c.1823A>G p.Y608C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770670015, COSV100218563; called by muse, mutect2, varscan2
- PIK3CD | c.787T>C p.C263R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100740021; called by muse, mutect2, varscan2
- PKN2 | c.232dup p.S78Kfs*14 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | catalogued as rs1335792632; called by mutect2, varscan2
- PKNOX2 | c.905T>C p.I302T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100020286; called by muse, mutect2, varscan2
- PLEKHH1 | c.809T>C p.M270T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV100232792; called by muse, mutect2, varscan2
- PLK1 | c.1574T>C p.L525P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99890794; called by muse, mutect2, varscan2
- PLVAP | c.1225A>T p.N409Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99391518; called by muse, mutect2, varscan2
- POLR2B | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100107905; called by muse, mutect2, varscan2
- PPFIA2 | c.1045A>G p.S349G | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100332002; called by muse, mutect2, varscan2
- PPM1D | c.1535dup p.N512Kfs*16 | Frame Shift Ins (INS) | VAF 11/24 reads (46%) | catalogued as rs763475304; called by mutect2, varscan2
- PRKCQ | c.1715T>C p.M572T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99576446; called by muse, mutect2, varscan2
- PTEN | c.485A>T p.D162V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64290065, COSV64301645; called by muse, mutect2, varscan2
- PTEN | c.800dup p.D268Gfs*30 | Frame Shift Ins (INS) | VAF 10/27 reads (37%) | catalogued as COSV64302388; called by mutect2, pindel, varscan2
- PTPN2 | c.667T>C p.S223P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100518389; called by muse, mutect2, varscan2
- PTPRN2 | c.548A>C p.E183A | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV101233858; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1163A>G p.D388G | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100365185; called by muse, mutect2, varscan2
- REXO5 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); catalogued as rs746852256, COSV54472009; called by muse, mutect2, varscan2
- RHOA | c.276A>G p.L92= | Splice Region (SNP) | VAF 6/39 reads (15%) | catalogued as COSV101371097; called by muse, mutect2, varscan2
- RMND5A | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1329379902; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RO60 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100814329; called by muse, mutect2, varscan2
- RP1 | c.2009G>A p.S670N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV99606511; called by muse, mutect2, varscan2
- RYR1 | c.12602G>A p.R4201H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.54); catalogued as rs1242322657, COSV100614868; called by muse, mutect2, varscan2
- SAMD15 | c.1316T>C p.L439P | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs751235178, COSV99374799; called by muse, varscan2
- SCN1A | c.4229A>G p.N1410S (on ENST00000303395 / NM_001202435.3; = p.N1399S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as CD126553, COSV100319575; called by muse, mutect2, varscan2
- SCN9A | c.1940A>C p.E647A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.309); catalogued as COSV100311732; called by muse, mutect2, varscan2
- SERTAD4 | c.840A>C p.K280N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV100882592; called by muse, mutect2, varscan2
- SETD5 | c.3614T>C p.I1205T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100200272; called by mutect2, varscan2
- SEZ6L | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1323504445, COSV99961349; called by muse, mutect2
- SLC10A4 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs146029985; called by muse, mutect2, varscan2
- SLC30A2 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs372456339; called by muse, mutect2, varscan2
- SLC30A3 | c.613dup p.H205Pfs*6 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | catalogued as rs745429257; called by mutect2, varscan2
- SMPD1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148892841; called by muse, mutect2
- SNRPA | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as rs775040575, COSV54680429; called by muse, mutect2, varscan2
- SPATA1 | c.658dup p.S220Kfs*8 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as rs762460676; called by mutect2, varscan2
- SPATA31E1 | c.3098T>C p.L1033P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.629); catalogued as COSV100350038; called by muse, mutect2, varscan2
- SRRM4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.05); catalogued as rs370817014; called by muse, mutect2, varscan2
- ST6GAL1 | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | PolyPhen possibly damaging (0.644); catalogued as COSV99398319; called by muse, mutect2, varscan2
- STARD13 | c.1147C>T p.R383C (on ENST00000336934 / NM_001243476.3; = p.R265C on NM_052851.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs757092348, COSV99715539; called by muse, mutect2
- SUGT1 | c.425-1G>T p.X142_splice (on ENST00000343788 / NM_001130912.3; = p.X110_splice on NM_006704.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100139368; called by muse, mutect2, varscan2
- SUN3 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as rs766880288, COSV52051828, COSV52054403; called by muse, mutect2, varscan2
- TESK1 | c.1162A>G p.R388G | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV99427311; called by muse, mutect2, varscan2
- TFDP3 | c.1139T>A p.V380E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100033249; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 18/43 reads (42%) | catalogued as rs782753958; called by mutect2, varscan2
- TFRC | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV100786395; called by muse, mutect2, varscan2
- TIMELESS | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1261579348, COSV99973718; called by muse, mutect2, varscan2
- TLE1 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100916262; called by muse, mutect2, varscan2
- TM4SF4 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.457); catalogued as COSV100541797; called by muse, mutect2, varscan2
- TMEM132D | c.618dup p.T207Hfs*29 | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | catalogued as rs747811524; called by mutect2, varscan2
- TMEM59 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs777400412, COSV52371305; called by muse, mutect2, varscan2
- TNFRSF19 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99947154; called by muse, mutect2, varscan2
- TNIP3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs764235001, COSV50246018, COSV99284504; called by muse, mutect2, varscan2
- TNKS2 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.437); catalogued as COSV100861016; called by muse, mutect2, varscan2
- TOP2B | c.470A>C p.Y157S (on ENST00000264331 / NM_001330700.2; = p.Y152S on NM_001068.3) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99979314; called by muse, mutect2, varscan2
- TRIM29 | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as COSV100531529; called by muse, mutect2, varscan2
- TRIM45 | c.176T>C p.F59S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV99868283; called by muse, mutect2, varscan2
- U2SURP | c.2298A>T p.E766D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV101204361; called by muse, mutect2, varscan2
- UBA5 | c.207+2T>C p.X69_splice | Splice Site (SNP) | VAF 15/31 reads (48%) | catalogued as COSV99393133; called by muse, mutect2, varscan2
- UNC13C | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99512797, COSV99522335; called by muse, mutect2, varscan2
- UNC79 | c.5841A>G p.I1947M (on ENST00000393151 / NM_001346218.2; = p.I1770M on NM_020818.5) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV99826254; called by muse, mutect2, varscan2
- USP14 | c.308T>C p.L103S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV99863860; called by mutect2, varscan2
- USP34 | c.10550A>G p.H3517R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as rs201379721; called by muse, mutect2, varscan2
- UVRAG | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs749559634, COSV100638217; called by muse, mutect2, varscan2
- WDR77 | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99330734; called by muse, mutect2, varscan2
- WNK2 | c.6271T>C p.S2091P (on ENST00000297954 / NM_001282394.1; = p.S2054P on NM_006648.3) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99941212; called by muse, mutect2, varscan2
- WNT4 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99268619; called by muse, mutect2, varscan2
- WNT8A | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100843020; called by muse, mutect2, varscan2
- YDJC | c.896T>C p.L299P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99488843; called by muse, mutect2, varscan2
- ZBTB46 | c.723C>G p.S241R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99828844; called by muse, mutect2
- ZBTB8A | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57142038; called by muse, mutect2, varscan2
- ZDHHC13 | c.1154T>C p.V385A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101239844; called by muse, mutect2, varscan2
- ZMYM5 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV100562576; called by muse, mutect2, varscan2
- ZNF234 | c.1421A>G p.H474R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101468339; called by muse, mutect2, varscan2
- ZNF292 | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100369954; called by muse, mutect2, varscan2
- ZNF333 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99468878; called by muse, mutect2, varscan2
- ZNF529 | c.1279T>C p.C427R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750697067, COSV100485112; called by muse, mutect2, varscan2
- ZNF609 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100440515; called by muse, mutect2, varscan2
- ZNF641 | c.429T>G p.C143W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV56390904, COSV99973387; called by muse, mutect2, varscan2
- ZNF799 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs750412987, COSV101345245; called by muse, mutect2, varscan2
- ZNRF1 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as rs1240412674, COSV100096790; called by muse, mutect2
- ZRANB3 | c.1648A>G p.T550A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV99922807; called by muse, mutect2, varscan2
- AP3B2 | c.3214dup p.M1072Nfs*56 (on ENST00000261722; = p.M1066Nfs*56 on NM_004644.5) | Frame Shift Ins (INS) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- ATPAF2 | c.785_787del p.L262del | In Frame Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 27/117 reads (23%) | called by mutect2, pindel, varscan2
- CCNL2 | c.1366dup p.Q456Pfs*24 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- CHD1 | c.1081dup p.R361Kfs*15 | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- CHD1 | c.513_514dup p.K172Rfs*78 | Frame Shift Ins (INS) | VAF 12/39 reads (31%) | called by mutect2, varscan2
- ESPL1 | c.6259G>C p.A2087P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FOLH1 | c.1627dup p.T543Nfs*15 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- FOS | c.418dup p.R140Kfs*9 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- GK | c.1623dup p.I542Yfs*4 (on ENST00000427190 / NM_001205019.2; = p.I536Yfs*4 on NM_001128127.2) | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- GOLT1B | c.186dup p.H63Tfs*2 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- GSPT2 | c.737dup p.N246Kfs*22 | Frame Shift Ins (INS) | VAF 14/28 reads (50%) | called by mutect2, varscan2
- HPX | c.210dup p.K71* | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by pindel, varscan2
- KAT5 | c.281_282dup p.V95Rfs*119 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, varscan2
- KMT2B | c.481del p.L161Ffs*6 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- MACF1 | c.13808dup p.P4605Afs*5 (on ENST00000372915; = p.P2538Afs*5 on NM_012090.5) | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- MROH8 | c.1704dup p.C570Vfs*6 | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | called by mutect2, varscan2
- OFD1 | c.2644del p.I882Yfs*6 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- OR5AC2 | c.101dup p.L34Ffs*49 | Frame Shift Ins (INS) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- OR7E24 | c.22_23insC p.F8Sfs*63 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by pindel, varscan2
- POLD1 | c.537dup p.R180Efs*72 | Frame Shift Ins (INS) | VAF 15/68 reads (22%) | called by mutect2, pindel, varscan2
- PPRC1 | c.513_514dup p.R172Lfs*45 | Frame Shift Ins (INS) | VAF 17/44 reads (39%) | called by mutect2, varscan2
- PTPRO | c.438dup p.Y147Ifs*2 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- RIT2 | c.382dup p.L128Pfs*6 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- SAGE1 | c.1793dup p.S599Lfs*9 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- SLAMF8 | c.648dup p.W217Lfs*3 | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- SMC3 | c.1100A>C p.Q367P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.484); called by muse, mutect2
- SNTN | c.237del p.A80Lfs*39 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- ST3GAL6 | c.350dup p.C118Vfs*6 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- STK11 | c.250_252dup p.K84dup | In Frame Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- SWT1 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM68 | c.352dup p.I118Nfs*26 | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.914T>C p.L305S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- U2SURP | c.3015dup p.S1006Ifs*17 | Frame Shift Ins (INS) | VAF 4/16 reads (25%) | called by mutect2, pindel, varscan2
- WDR25 | c.177dup p.A60Sfs*12 | Frame Shift Ins (INS) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- WDR5 | c.648del p.V217Cfs*4 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- WDR81 | c.4671dup p.T1558Dfs*16 (on ENST00000409644 / NM_001163809.2; = p.T507Dfs*16 on NM_152348.4) | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- AFAP1L2 | c.945T>G p.P315= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100412234; called by muse, mutect2, varscan2
- AGPAT4 | c.1077G>A p.T359= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs761694107, COSV100211072; called by muse, mutect2, varscan2
- AHNAK | c.11670T>C p.D3890= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as rs750053281; called by muse, mutect2, varscan2
- ALDOA | c.780C>A p.T260= (on ENST00000642816 / NM_001243177.4; = p.T206= on NM_184041.5) | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100581952, COSV57632915; called by muse, mutect2, varscan2
- ARHGAP11A | c.150T>C p.P50= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100853177; called by mutect2, varscan2
- ARHGEF40 | c.1996A>C p.R666= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV100070090; called by muse, mutect2, varscan2
- ASF1B | c.205A>C p.R69= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99654236; called by muse, varscan2
- ATM | c.8265T>C p.Y2755= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs758654836, BM1444367, COSV53734127, COSV99587868; ClinVar: likely benign; called by muse, mutect2
- C17orf80 | c.9T>C p.D3= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99277895; called by muse, mutect2
- CCDC62 | c.366G>A p.T122= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs145920110; called by muse, mutect2, varscan2
- CDH10 | c.585C>T p.S195= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs763323957, COSV52578565, COSV52590852; called by muse, mutect2, varscan2
- CDK9 | c.1014C>T p.Y338= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100953621; called by muse, mutect2, varscan2
- CDKL2 | c.180T>C p.H60= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100276772; called by muse, mutect2, varscan2
- CMAS | c.999G>A p.T333= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs553811352, COSV99982572; called by muse, mutect2, varscan2
- DNAH7 | c.11811A>G p.R3937= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100414160; called by muse, mutect2, varscan2
- EBF3 | c.972C>T p.V324= (on ENST00000355311 / NM_001375392.1; = p.V315= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs138715526; called by muse, mutect2, varscan2
- ETFDH | c.1068A>G p.G356= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100309799; called by muse, mutect2
- EXOC4 | c.2013A>G p.E671= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1157359775, COSV99552661; called by muse, mutect2, varscan2
- FAHD1 | c.15A>G p.A5= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101232494; called by muse, mutect2, varscan2
- FAM133A | c.45A>G p.A15= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100220200; called by muse, mutect2, varscan2
- GPR45 | c.363C>T p.G121= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV51522980; called by muse, mutect2, varscan2
- HECW1 | c.2541T>C p.Y847= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV101222970; called by muse, mutect2, varscan2
- HOOK3 | c.96G>A p.V32= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs764554162, COSV100295136; called by muse, varscan2
- HS3ST2 | c.603C>T p.I201= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs989036495, COSV54466235, COSV99757734; called by muse, mutect2, varscan2
- HTR1A | c.1200C>T p.Y400= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV60500110; called by muse, mutect2, varscan2
- JAML | c.931T>C p.L311= (on ENST00000356289 / NM_001098526.2; = p.L301= on NM_153206.3) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99409312; called by muse, mutect2, varscan2
- KANK4 | c.1947C>T p.D649= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100587150; called by muse, mutect2, varscan2
- LMTK3 | c.3534C>T p.P1178= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs762705500, COSV99540035; called by muse, mutect2
- LPIN2 | c.774A>G p.S258= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV55239175; called by muse, mutect2, varscan2
- MAG | c.783T>C p.C261= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100727645; called by muse, mutect2
- MAP4 | c.1602A>G p.V534= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100805462; called by muse, mutect2, varscan2
- MARF1 | c.741G>A p.T247= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs765342395, COSV100705632; called by mutect2, varscan2
- MAS1L | c.282C>T p.G94= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs778887057, COSV101009650; called by muse, mutect2, varscan2
- MCRS1 | c.597T>C p.A199= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100657302; called by muse, mutect2, varscan2
- MED13 | c.609A>G p.P203= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1425321771, COSV100784895; called by muse, mutect2, varscan2
- MSI1 | c.837A>G p.A279= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs751007952, COSV99981395; called by muse, mutect2, varscan2
- MYBPC2 | c.1380C>T p.C460= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs373913738; called by muse, mutect2, varscan2
- MYT1L | c.480G>A p.E160= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs755865898, COSV101219245; called by muse, mutect2, varscan2
- NCAPH2 | c.1503A>G p.T501= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99329375; called by muse, mutect2
- NRDE2 | c.702C>T p.I234= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs752480912, COSV100583320; called by muse, mutect2, varscan2
- OR2AG1 | c.744T>C p.V248= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs745558101, COSV100264824; called by muse, varscan2
- ORC1 | c.1575T>C p.H525= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs770310076, COSV100856608; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDH17 | c.2451A>G p.K817= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs1281903708, COSV100931472; called by muse, mutect2, varscan2
- PCDHB16 | c.1665C>T p.N555= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs782078950, COSV53362553; called by mutect2, varscan2
- PCDHGA7 | c.921A>G p.L307= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99532747; called by muse, mutect2, varscan2
- PDZRN3 | c.1317G>A p.T439= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs542152332, COSV55205309; called by muse, varscan2
- PSG7 | c.51G>T p.G17= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV101343209; called by muse, mutect2, varscan2
- PTAFR | c.12T>C p.H4= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100544277; called by mutect2, varscan2
- QRICH2 | c.1287A>G p.A429= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV99428868; called by muse, mutect2, varscan2
- RYR2 | c.11541T>C p.C3847= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100768569; called by muse, mutect2, varscan2
- SH2B1 | c.1446C>A p.P482= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100450925; called by muse, mutect2, varscan2
- SHC1 | c.1632T>C p.T544= (on ENST00000368445 / NM_183001.5; = p.T435= on NM_003029.5) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100820973; called by muse, mutect2, varscan2
- SLC2A12 | c.54A>T p.T18= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs770572791, COSV99259723; called by muse, mutect2, varscan2
- SLC4A9 | c.1608C>T p.S536= (on ENST00000507527 / NM_001258428.2; = p.S512= on NM_031467.3) | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs751458919, COSV99138502; called by muse, mutect2, varscan2
- SLC51A | c.732G>A p.R244= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99491981; called by muse, mutect2, varscan2
- SMOX | c.132T>C p.L44= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99602936; called by muse, mutect2, varscan2
- SRRM1 | c.1951A>C p.R651= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100104196; called by muse, mutect2, varscan2
- SYT7 | c.1095C>T p.D365= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs145753051, COSV55658175; called by muse, mutect2, varscan2
- TLE3 | c.315G>A p.A105= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs557301183, COSV58169006; called by muse, mutect2, varscan2
- TOGARAM2 | c.327T>G p.S109= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV101090928; called by muse, mutect2, varscan2
- TOM1L2 | c.510T>C p.P170= (on ENST00000379504 / NM_001350333.2; = p.P120= on NM_001033551.3) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100540917; called by muse, mutect2, varscan2
- TRIM40 | c.51C>T p.C17= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100325269; called by muse, mutect2, varscan2
- TTC3 | c.999T>C p.P333= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100695158; called by muse, mutect2, varscan2
- TUBB4A | c.1092C>T p.A364= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs142838372; called by muse, mutect2, varscan2
- UTP6 | c.1746A>C p.A582= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99911826; called by muse, mutect2, varscan2
- VIP | c.234T>C p.N78= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs368188208; called by muse, mutect2, varscan2
- VIRMA | c.4788T>C p.H1596= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99887828; called by muse, mutect2, varscan2
- WASF2 | c.1185T>C p.P395= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV71005965; called by muse, mutect2, varscan2
- WDR93 | c.1404G>A p.S468= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs767559950, COSV99175492; called by muse, mutect2, varscan2
- ZNF516 | c.2985T>G p.P995= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV101487221; called by muse, mutect2, varscan2
- ZNF606 | c.891T>C p.S297= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV62048875; called by muse, mutect2, varscan2
- ALG13 | c.383+2899A>G | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as rs1433611489, COSV99321776; called by muse, varscan2
- POLH | c.*5698T>C | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- SNORD116-6 | n.28dup | RNA (INS) | VAF 14/40 reads (35%) | catalogued as rs745917119; called by mutect2, varscan2
- TSR1 | c.1903+159dup | Intron (INS) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- VPS11 | c.-338G>A | 5'UTR (SNP) | VAF 7/19 reads (37%) | catalogued as COSV56183691; called by muse, mutect2, varscan2
